Gene-level copy-number profile of tumor specimen TCGA-RW-A688-01A from TCGA case TCGA-RW-A688, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 69.0 years (25,216 days).
Specimen TCGA-RW-A688-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PCPG.168ecf51-ddd7-4871-8aa9-fc6d65a6dac0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-RW-A688-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/497f7d68-0ed0-41bb-9476-a5aea37a9b00

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 5,608; copy number 2: 50,023; copy number 3: 4,180; copy number 4: 2; copy number 5: 7.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-RW-A688-01A-11D-A35C-01): tumor purity 0.9, ploidy 2, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 7 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:55,951,654–56,181,652, 7 genes, copy number 5 (within-gene range 2–5): RN7SKP208, AC011306.1, MIR217HG, MIR217, MIR216A, MIR216B, LINC01813.

Autosomal genes at a single copy (total copy number 1): 5,608. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
